Somatic mutation profile of tumor specimen TCGA-QR-A70P-01A (aliquot TCGA-QR-A70P-01A-11D-A35D-08) from TCGA case TCGA-QR-A70P, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 45.6 years (16,655 days).
Specimen TCGA-QR-A70P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bc79219-7378-4614-a66c-a87134db0fc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70P-10A (Blood Derived Normal), aliquot TCGA-QR-A70P-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bed18883-d7b2-4ed8-8ed5-f81d828bbd15

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 14, Silent 8, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LGALS9B | c.839G>A p.R280H (on ENST00000423676 / NM_001367292.1; = p.R279H on NM_001042685.2) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as rs774430805; called by mutect2, varscan2
- MTR | c.3085C>T p.R1029W | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs139771804; called by muse, mutect2, varscan2
- MUC16 | c.12346G>A p.A4116T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.634); catalogued as COSV101200009; called by muse, mutect2, varscan2
- PAX1 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1363850821; called by muse, mutect2, varscan2
- RNF10 | c.1672C>T p.R558* | Nonsense Mutation (SNP) | VAF 43/121 reads (36%) | catalogued as rs774506367, COSV58048663; called by muse, mutect2, varscan2
- SEMG2 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs761534127; called by muse, mutect2, varscan2
- SIX4 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1442875808; called by muse, mutect2, varscan2
- SUPT7L | c.1193G>C p.G398A | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.219); catalogued as rs763182708; called by muse, mutect2, varscan2
- TANC2 | c.5906G>A p.R1969Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.551); catalogued as rs143701650; called by muse, mutect2, varscan2
- VIT | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs927057909, COSV99061760; called by muse, mutect2
- COL6A3 | c.3071T>A p.V1024D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF15 | c.1830-2A>G p.X610_splice | Splice Site (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- NCKAP1L | c.2142G>C p.E714D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNPEPL1 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SIX4 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC44A1 | c.1483T>A p.Y495N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CKAP5 | c.3261C>T p.P1087= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- FAM71A | c.69C>T p.T23= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- KRTAP12-3 | c.69C>T p.S23= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV59961396; called by muse, mutect2, varscan2
- NDUFS8 | c.306C>T p.R102= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1166924613; called by mutect2, varscan2
- RSBN1 | c.621C>T p.C207= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs147797898; called by muse, mutect2, varscan2
- SPAG17 | c.4692G>A p.E1564= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs760333950, COSV100310839; called by muse, mutect2, varscan2
- TOGARAM2 | c.540C>T p.S180= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1463090235; called by muse, mutect2
- VSIG4 | c.1011C>T p.A337= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs1462517168; called by muse, mutect2, varscan2
